Somatic mutation profile of tumor specimen TCGA-ZH-A8Y7-01A (aliquot TCGA-ZH-A8Y7-01A-21D-A46P-09) from TCGA case TCGA-ZH-A8Y7, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 59.9 years (21,880 days).
Specimen TCGA-ZH-A8Y7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6be360d8-efc5-49dd-b117-c43fc7bf9ca8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZH-A8Y7-10A (Blood Derived Normal), aliquot TCGA-ZH-A8Y7-10A-01D-A46P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46e92822-8430-437a-a670-6432e2eed044

The open-access MAF lists 916 somatic variants for this specimen: 686 protein-altering or splice-affecting, 211 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 425, Silent 211, Frame Shift Del 154, Frame Shift Ins 47, Nonsense Mutation 24, In Frame Del 21, Splice Site 10, Intron 7, RNA 4, 3'UTR 4, Splice Region 3, Nonstop Mutation 2.

Variants (750 of 916; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX12B | c.1350del p.L451Sfs*16 | Frame Shift Del (DEL) | VAF 32/131 reads (24%) | catalogued as rs746723399, COSV59872823; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CEP290 | c.6869del p.N2290Ifs*11 | Frame Shift Del (DEL) | VAF 61/176 reads (35%) | catalogued as rs587783017, CD075343; ClinVar: pathogenic; called by mutect2, varscan2
- COL4A1 | c.2085dup p.G696Rfs*6 | Frame Shift Ins (INS) | VAF 29/150 reads (19%) | catalogued as rs606231464; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- F11 | c.990dup p.T331Yfs*28 | Frame Shift Ins (INS) | VAF 24/74 reads (32%) | catalogued as rs1554082938; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- FBN1 | c.5183C>T p.A1728V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1131691804, CM115514, COSV100356139; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.1810G>A p.G604S | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199473522, CM990760; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 12/64 reads (19%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- PAFAH1B1 | c.162del p.K54Nfs*15 | Frame Shift Del (DEL) | VAF 66/238 reads (28%) | catalogued as rs113994198; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 34/105 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1425+1G>A p.X475_splice (on ENST00000521381 / NM_181523.3; = p.X205_splice on NM_181504.4) | Splice Site (SNP) | VAF 27/68 reads (40%) | hotspot (GDC flag); catalogued as rs587777709, CS148401, CS148402, CS164183, COSV57123381, COSV57132744, COSV57140308; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PROM1 | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1302809734; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PTCH1 | c.290del p.N97Tfs*20 | Frame Shift Del (DEL) | VAF 116/268 reads (43%) | catalogued as rs1554708751, CD066395, CX962597; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RIN2 | c.1878dup p.I627Hfs*7 (on ENST00000255006 / NM_001242581.1; = p.I578Hfs*7 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 29/78 reads (37%) | catalogued as rs759390822; ClinVar: pathogenic; called by mutect2, varscan2
- STAT5B | c.1102dup p.Q368Pfs*9 | Frame Shift Ins (INS) | VAF 26/52 reads (50%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 18/27 reads (67%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1429920034; called by muse, mutect2, varscan2
- ABCB6 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1335429025, COSV99521900; called by muse, mutect2, varscan2
- ABCB9 | c.1498C>A p.L500M (on ENST00000280560 / NM_019625.4; = p.L457M on NM_019624.3) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.206); catalogued as COSV54890587; called by muse, mutect2, varscan2
- ABHD2 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs757210313, COSV100756383, COSV61775010; called by muse, mutect2, varscan2
- ABTB1 | c.725C>T p.A242V (on ENST00000232744 / NM_172027.3; = p.A100V on NM_032548.3) | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as rs370328576; called by muse, mutect2, varscan2
- AC090517.4 | c.1783del p.S595Vfs*7 | Frame Shift Del (DEL) | VAF 21/72 reads (29%) | catalogued as rs1157171684; called by mutect2, pindel, varscan2
- ACCSL | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs371000393, COSV66580564; called by muse, mutect2, varscan2
- ACHE | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs368062416; called by muse, mutect2, varscan2
- ACP6 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs782414489, COSV100984265; called by muse, mutect2, varscan2
- ADCY1 | c.2390C>T p.A797V | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as rs368337715; called by muse, mutect2, varscan2
- ADCY5 | c.3313G>A p.A1105T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1451387994, COSV59197369; called by muse, mutect2, varscan2
- ADGRB1 | c.2301C>A p.D767E | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.152); catalogued as rs1486079710; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs761350619; called by mutect2, varscan2
- ADNP2 | c.971del p.P324Lfs*8 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | catalogued as rs772825390; called by mutect2, pindel, varscan2
- AHDC1 | c.3812C>T p.P1271L | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1354553377, COSV99898729; called by muse, mutect2, varscan2
- ALG12 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 4/44 reads (9%) | PolyPhen probably damaging (0.973); catalogued as rs201405631; ClinVar: uncertain significance; called by mutect2, varscan2
- AMDHD1 | c.442G>C p.A148P | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.702); catalogued as COSV57140691; called by muse, mutect2, varscan2
- ANKRD24 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs758310661, COSV53668981; called by muse, mutect2, varscan2
- ANKRD35 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as rs376866282; called by muse, mutect2, varscan2
- ANO2 | c.1004G>A p.R335H (on ENST00000356134 / NM_001278597.3; = p.R339H on NM_001278596.3) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs1486183196, COSV59028580; called by muse, mutect2, varscan2
- APOE | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs11083750; called by muse, mutect2, varscan2
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as rs776520069; called by mutect2, varscan2
- ARL13B | c.932del p.N311Ifs*6 (on ENST00000394222 / NM_001174150.2; = p.N204Ifs*6 on NM_144996.4) | Frame Shift Del (DEL) | VAF 20/151 reads (13%) | catalogued as rs750642821; called by mutect2, pindel, varscan2
- ARL6IP4 | c.1246C>T p.R416* (on ENST00000315580 / NM_018694.3; = p.R397* on NM_016638.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as rs547980550, COSV54898047; called by mutect2, varscan2
- ASAH2 | c.148del p.S50Qfs*40 | Frame Shift Del (DEL) | VAF 21/118 reads (18%) | catalogued as rs772181094; called by mutect2, varscan2
- ATCAY | c.360C>T p.D120= | Splice Region (SNP) | VAF 15/59 reads (25%) | catalogued as rs758678492, COSV56658098; called by muse, mutect2, varscan2
- ATG4B | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.072); catalogued as rs1186967714; called by muse, mutect2, varscan2
- ATP5IF1 | c.247_249del p.K83del | In Frame Del (DEL) | VAF 13/57 reads (23%) | catalogued as rs746429737; called by pindel, varscan2
- AVL9 | c.1774dup p.I592Nfs*9 | Frame Shift Ins (INS) | VAF 19/118 reads (16%) | catalogued as rs1431700908; called by mutect2, varscan2
- AXDND1 | c.2980G>C p.E994Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.81); catalogued as rs754952987, COSV62642121; called by muse, mutect2, varscan2
- BAIAP2L1 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765327861, COSV50057558; called by muse, mutect2, varscan2
- BAZ2A | c.3262C>T p.R1088C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs776907008, COSV51643345; called by muse, mutect2, varscan2
- BBS12 | c.1480del p.T494Qfs*37 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as COSV58561996; called by mutect2, pindel, varscan2
- BCAS3 | c.1666T>C p.S556P | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.976); catalogued as COSV101175595, COSV66770827; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs755506199; called by mutect2, varscan2
- BRCA2 | c.3376G>A p.E1126K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66458745, COSV66462210; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 44/88 reads (50%) | catalogued as rs763134487; called by mutect2, varscan2
- BSCL2 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs761806607; called by muse, mutect2, varscan2
- BTF3L4 | c.135dup p.L46Tfs*5 | Frame Shift Ins (INS) | VAF 23/88 reads (26%) | catalogued as rs1558005082; called by mutect2, varscan2
- C19orf57 | c.1224del p.G409Afs*4 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as rs35608314; called by mutect2, pindel, varscan2
- C3 | c.2500C>T p.R834W | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758900962, COSV55580718; called by muse, mutect2, varscan2
- C5 | c.2185A>G p.T729A | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.039); catalogued as rs138577779; called by muse, mutect2, varscan2
- CADM1 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1012431388; called by muse, mutect2, varscan2
- CAMTA1 | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.35); catalogued as rs754943704; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAND2 | c.1213C>T p.R405W (on ENST00000456430 / NM_001162499.2; = p.R312W on NM_012298.3) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs746550726; called by muse, mutect2
- CAND2 | c.2417G>A p.R806Q (on ENST00000456430 / NM_001162499.2; = p.R713Q on NM_012298.3) | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as rs551851915; called by muse, mutect2, varscan2
- CC2D2A | c.4852C>T p.R1618C | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201219078; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCAR2 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.318); catalogued as rs748279690; called by muse, mutect2, varscan2
- CCDC9 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs368381443, COSV55720439; called by muse, mutect2, varscan2
- CCN1 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1205757605, COSV71704323; called by muse, mutect2, varscan2
- CCNYL1 | c.1012G>A p.A338T (on ENST00000295414 / NM_001330218.2; = p.A268T on NM_152523.2) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs528503126; called by muse, mutect2, varscan2
- CCSER1 | c.2003C>A p.P668H | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs763527271; called by muse, mutect2, varscan2
- CD93 | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1176188672; called by muse, mutect2, varscan2
- CDC16 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs142528073; called by muse, mutect2, varscan2
- CDH1 | c.1009_1010del p.X337_splice | Splice Site (DEL) | VAF 24/84 reads (29%) | catalogued as rs786201045; called by pindel, varscan2
- CDHR2 | c.2204C>T p.S735L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as rs376123961; called by muse, mutect2, varscan2
- CDYL | c.985C>T p.R329C (on ENST00000328908 / NM_001368125.1; = p.R275C on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV59358466; called by muse, mutect2, varscan2
- CEBPE | c.836del p.G279Vfs*19 | Frame Shift Del (DEL) | VAF 24/87 reads (28%) | catalogued as rs1363394381, COSV52829926; called by mutect2, pindel, varscan2
- CERK | c.1428del p.K477Rfs*74 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs761362852; called by mutect2, varscan2
- CFAP47 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV99934415; called by muse, mutect2, varscan2
- CHRM3 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs780261877, COSV99697438; called by muse, mutect2, varscan2
- CLCA1 | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs745353236; called by muse, mutect2, varscan2
- CLCC1 | c.1279_1280dup p.D427Efs*5 (on ENST00000356970 / NM_001377464.1; = p.D377Efs*5 on NM_015127.5) | Frame Shift Ins (INS) | VAF 20/72 reads (28%) | catalogued as rs750385149; called by mutect2, varscan2
- CLIP2 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs782715037; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | catalogued as rs369752219; called by mutect2, varscan2
- CLUH | c.1324del p.D442Tfs*12 (on ENST00000435359; = p.D480Tfs*12 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as rs752224729; called by pindel, varscan2*
- COBLL1 | c.3163C>T p.P1055S (on ENST00000392717; = p.P1017S on NM_014900.5) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52072851; called by muse, mutect2, varscan2
- COL24A1 | c.3905C>T p.S1302L | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs1558235230; called by muse, mutect2, varscan2
- COL4A2 | c.4275dup p.G1426Rfs*30 | Frame Shift Ins (INS) | VAF 11/46 reads (24%) | catalogued as rs34603892; called by mutect2, varscan2
- COL5A3 | c.4241del p.P1414Rfs*46 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | catalogued as COSV53410357; called by mutect2, pindel, varscan2
- COX6C | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.155); catalogued as rs766823907, COSV99881935; called by muse, mutect2, varscan2
- CPAMD8 | c.2779G>A p.D927N (on ENST00000651564; = p.D880N on NM_015692.5) | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as rs1021225057; called by muse, varscan2
- CPAMD8 | c.2521G>A p.A841T (on ENST00000651564; = p.A794T on NM_015692.5) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770942297; called by muse, mutect2, varscan2
- CPLX2 | c.229_231del p.E77del | In Frame Del (DEL) | VAF 15/53 reads (28%) | catalogued as rs770953273; called by pindel, varscan2
- CPXM2 | c.1478C>T p.T493M | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs143241838; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 27/100 reads (27%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSNK1G3 | c.888del p.F296Lfs*9 | Frame Shift Del (DEL) | VAF 61/280 reads (22%) | catalogued as rs1192761448; called by mutect2, pindel, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 31/91 reads (34%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CTNNBL1 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs1467718459, COSV63747547; called by muse, mutect2, varscan2
- CTSV | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.337); catalogued as rs757379479, COSV52344154; called by muse, mutect2, varscan2
- CUX1 | c.1565G>A p.R522H (on ENST00000437600 / NM_181500.4; = p.R524H on NM_001913.5) | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1554548105, COSV99476629; called by muse, mutect2, varscan2
- CX3CL1 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as rs199662906, COSV50057070; called by muse, mutect2, varscan2
- CYFIP2 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59028234; called by muse, mutect2, varscan2
- DCAF12L2 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as COSV63580157; called by muse, mutect2, varscan2
- DCAF5 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as rs757111344; called by muse, mutect2, varscan2
- DCC | c.4168G>C p.A1390P | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as COSV71431781; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 68/121 reads (56%) | catalogued as rs766714372; called by mutect2, varscan2
- DGKZ | c.2306G>A p.R769Q (on ENST00000454345 / NM_001105540.2; = p.R581Q on NM_003646.4) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV58994219; called by muse, mutect2, varscan2
- DHX9 | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62358157; called by muse, mutect2, varscan2
- DIS3L | c.1927C>T p.R643* (on ENST00000319212 / NM_001143688.3; = p.R560* on NM_133375.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as rs1339562677, COSV59911969; called by muse, mutect2, varscan2
- DLGAP2 | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs780191233; called by muse, mutect2, varscan2
- DLGAP3 | c.346dup p.R116Pfs*11 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | catalogued as rs773184820; called by mutect2, pindel, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 50/166 reads (30%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH1 | c.10151G>A p.R3384H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs781434212, COSV70228496; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH17 | c.2196G>T p.K732N | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV67754524; called by muse, mutect2, varscan2
- DOCK5 | c.4400C>T p.P1467L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs772062014; called by muse, mutect2, varscan2
- DOCK9 | c.5705C>T p.T1902M (on ENST00000376460 / NM_001366676.2; = p.T1903M on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159046563; called by muse, mutect2, varscan2
- DROSHA | c.110A>C p.Q37P | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.099); catalogued as rs569160930, COSV60783690; called by muse, mutect2, varscan2
- DYNC1H1 | c.12214G>A p.G4072S | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794815; called by muse, mutect2, varscan2
- DYSF | c.5665_5667del p.K1889del | In Frame Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs752228768; called by pindel, varscan2
- EAF2 | c.334del p.T112Qfs*30 | Frame Shift Del (DEL) | VAF 45/194 reads (23%) | catalogued as rs746509911; called by mutect2, varscan2
- ECPAS | c.3643C>T p.R1215* | Nonsense Mutation (SNP) | VAF 28/103 reads (27%) | catalogued as COSV52203496; called by muse, mutect2, varscan2
- EEF2 | c.1315_1317del p.K439del | In Frame Del (DEL) | VAF 20/80 reads (25%) | catalogued as rs1195137689; called by pindel, varscan2
- EHD2 | c.1160C>T p.T387M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs975000304; called by muse, varscan2
- EIPR1 | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs781124556; called by muse, mutect2, varscan2
- EPHB6 | c.2762G>A p.R921H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs758096886, COSV63892832, COSV63894038; called by muse, mutect2, varscan2
- EVA1A | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770469485, COSV52059031; called by muse, mutect2, varscan2
- EVA1C | c.1034_1035del p.E345Vfs*21 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs1474174643; called by pindel, varscan2
- EXTL3 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs146905864; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs766589051; called by mutect2, varscan2
- FAM161B | c.551C>T p.P184L (on ENST00000651776; = p.P121L on NM_152445.3) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as rs141443228; called by muse, mutect2, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAM217B | c.611dup p.K205Qfs*21 | Frame Shift Ins (INS) | VAF 30/107 reads (28%) | catalogued as rs762805656; called by mutect2, pindel, varscan2
- FAM71C | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV100175779; called by muse, mutect2, varscan2
- FAT2 | c.3039_3040del p.C1014Pfs*11 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs1403793825; called by pindel, varscan2
- FBXL19 | c.614del p.P205Rfs*26 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs745385709; called by mutect2, varscan2
- FBXO40 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs142245957; called by muse, mutect2, varscan2
- FCGBP | c.8228C>T p.A2743V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs372938963; called by muse, mutect2, varscan2
- FCGBP | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs764838488; called by muse, mutect2, varscan2
- FGD4 | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1025203055, COSV56781619; called by muse, mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as rs144178676; called by mutect2, varscan2
- FKBP3 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs371278010; called by muse, mutect2, varscan2
- FLNA | c.4834G>A p.V1612M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs782082407; called by muse, mutect2, varscan2
- FUBP3 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs750936198; called by muse, mutect2, varscan2
- GABRG3 | c.543C>A p.D181E | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61531497; called by muse, mutect2, varscan2
- GCNT3 | c.497A>G p.E166G | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as rs1243748512; called by muse, mutect2, varscan2
- GLI2 | c.1366C>T p.R456C (on ENST00000361492 / NM_001374353.1; = p.R473C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs370251398; called by muse, mutect2, varscan2
- GMPR | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368739126; called by muse, mutect2, varscan2
- GPRC5B | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.062); catalogued as rs371877366, COSV56027704; called by muse, mutect2, varscan2
- GRK2 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as rs753435050; called by muse, mutect2, varscan2
- GRM1 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51117094; called by muse, mutect2, varscan2
- GRM6 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs369887161; called by muse, mutect2, varscan2
- H1-4 | c.41del p.P14Lfs*7 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | catalogued as COSV56800502; called by mutect2, pindel, varscan2
- HLA-DOA | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.861); catalogued as rs200187983, COSV57715079; called by muse, varscan2
- HOXA7 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs1207033824; called by muse, mutect2, varscan2
- HRH3 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1277870064, COSV58048757; called by muse, mutect2, varscan2
- HTR3D | c.938G>A p.C313Y (on ENST00000382489 / NM_001163646.2; = p.C138Y on NM_182537.3) | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs527414962; called by muse, mutect2, varscan2
- HUS1B | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV57872085; called by muse, mutect2, varscan2
- IBA57 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751210041; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 14/115 reads (12%) | catalogued as rs747841314; called by mutect2, varscan2
- IDH1 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV61619722; called by muse, mutect2, varscan2
- IFITM1 | c.139T>A p.L47M | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs748890801; called by muse, mutect2, varscan2
- IGFN1 | c.1867G>A p.V623M (on ENST00000295591 / NM_001367841.1; = p.V3080M on NM_001164586.2) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs372638363; called by muse, mutect2, varscan2
- IGSF9 | c.154del p.L52Cfs*79 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as rs753928344; called by mutect2, pindel, varscan2
- INHBC | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs766716581, COSV100548051; called by muse, mutect2, varscan2
- IQCC | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV52210496; called by muse, mutect2, varscan2
- ITGAD | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs1326391815; called by muse, mutect2, varscan2
- ITGAM | c.2488C>T p.R830W (on ENST00000648685 / NM_001145808.2; = p.R829W on NM_000632.4) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200357959, COSV54938841; called by muse, mutect2, varscan2
- ITGAM | c.3047G>A p.R1016Q (on ENST00000648685 / NM_001145808.2; = p.R1015Q on NM_000632.4) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868496082, COSV99792444; called by muse, mutect2, varscan2
- ITPR3 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1370671417, COSV100967945; called by muse, mutect2, varscan2
- IVL | c.1615C>T p.Q539* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as rs1481405411; called by muse, mutect2, varscan2
- JAM3 | c.745dup p.V249Gfs*28 | Frame Shift Ins (INS) | VAF 40/154 reads (26%) | catalogued as rs763250381; called by mutect2, varscan2
- JUP | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs199511559, COSV60277833; ClinVar: uncertain significance; called by muse, varscan2
- KATNIP | c.4517C>T p.A1506V | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs150197704; called by muse, varscan2
- KCNA6 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99768467; called by muse, mutect2, varscan2
- KCNH5 | c.2890dup p.Q964Pfs*9 | Frame Shift Ins (INS) | VAF 62/264 reads (23%) | catalogued as rs35940222; called by mutect2, varscan2
- KCNH6 | c.2176del p.R726Dfs*61 | Frame Shift Del (DEL) | VAF 37/124 reads (30%) | catalogued as COSV59005895; called by mutect2, pindel, varscan2
- KCNN4 | c.64_66del p.E22del | In Frame Del (DEL) | VAF 13/67 reads (19%) | catalogued as rs751361496; called by mutect2, pindel, varscan2
- KCNQ4 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs574794136; called by muse, mutect2, varscan2
- KDM1B | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.21); catalogued as COSV52808407; called by muse, mutect2
- KIAA0895L | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs776428830, COSV51782665; called by muse, mutect2, varscan2
- KIAA1522 | c.320_322del p.S107del (on ENST00000373480 / NM_001198972.2; = p.S166del on NM_020888.3) | In Frame Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs1414493744; called by mutect2, pindel, varscan2
- KIAA1549L | c.5390C>T p.P1797L (on ENST00000321505; = p.P2094L on NM_012194.3) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs755901261; called by muse, mutect2, varscan2
- KIAA2026 | c.2187del p.A730Qfs*26 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs749990720; called by mutect2, varscan2
- KIF21B | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1380566315, COSV59753238; called by muse, mutect2
- KIF6 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs757976747, COSV54667341; called by muse, mutect2
- KIF9 | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as rs114109244, COSV55519383; called by muse, mutect2, varscan2
- KIR3DL2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs750759932; called by muse, mutect2, varscan2
- KIRREL3 | c.464del p.G155Afs*3 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | catalogued as rs1565483272; called by mutect2, pindel, varscan2
- KLHL22 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.118); catalogued as rs867222477, COSV61019924; called by muse, mutect2, varscan2
- KLHL36 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.417); catalogued as rs1178678605; called by muse, mutect2, varscan2
- KLHL36 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1483586504, COSV50720342; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs749194179; called by mutect2, varscan2
- KMT2B | c.5730del p.R1911Dfs*23 | Frame Shift Del (DEL) | VAF 34/116 reads (29%) | catalogued as COSV55867385; called by mutect2, pindel, varscan2
- KMT2D | c.16213C>T p.R5405C | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771584280; called by muse, varscan2
- KMT2D | c.15871G>A p.E5291K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs936142615, COSV56460833; called by muse, mutect2
- KRT5 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758181003; called by muse, mutect2, varscan2
- KRTAP24-1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.054); catalogued as rs1309676554, COSV99080090; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LILRA4 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs139101339; called by muse, varscan2
- LMNTD1 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 32/109 reads (29%) | catalogued as rs756057727, COSV99280274; called by muse, mutect2, varscan2
- LPGAT1 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as rs759081626; called by muse, mutect2, varscan2
- LRRN4 | c.979_980del p.K327Efs*84 | Frame Shift Del (DEL) | VAF 36/145 reads (25%) | catalogued as rs764789750; called by mutect2, pindel, varscan2
- MAN1A2 | c.1627C>T p.R543* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as rs775702950; called by muse, mutect2, varscan2
- MARCHF2 | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs202077510; called by muse, mutect2, varscan2
- MARF1 | c.3109G>A p.D1037N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.135); catalogued as rs368140283; called by muse, mutect2, varscan2
- MAST3 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs199503705, COSV53225421; called by muse, mutect2, varscan2
- MBD6 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV63076714; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MFSD1 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as rs753535023, COSV51843367; called by muse, mutect2, varscan2
- MGAT4B | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1047960020, COSV52977482; called by muse, mutect2, varscan2
- MIA3 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs372980758; called by muse, mutect2, varscan2
- MICALL2 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs372954819; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MINK1 | c.2383C>T p.R795W | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1449922653, COSV53418475; called by muse, mutect2, varscan2
- MISP | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1185960926; called by muse, mutect2, varscan2
- MPRIP | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs566850945, COSV100506174; called by muse, mutect2, varscan2
- MRC2 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); catalogued as rs772992810, COSV57636113; called by muse, mutect2, varscan2
- MROH1 | c.2812C>T p.R938W | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs1200107487; called by muse, mutect2
- MSL1 | c.1573A>T p.I525F (on ENST00000398532 / NM_001365919.1; = p.I262F on NM_001012241.2) | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.303); catalogued as COSV59899214; called by muse, mutect2, varscan2
- MTF1 | c.2224del p.E742Rfs*90 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as COSV65988475; called by mutect2, pindel, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | catalogued as rs759847587; called by mutect2, varscan2
- MTG1 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs568280190, COSV58153849; called by muse, mutect2, varscan2
- MTIF2 | c.1974dup p.F659Ifs*2 | Frame Shift Ins (INS) | VAF 16/65 reads (25%) | catalogued as rs770359991; called by mutect2, varscan2
- MTMR10 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); catalogued as rs757901805, COSV58728360; called by muse, mutect2, varscan2
- MTRR | c.1369G>A p.A457T (on ENST00000264668; = p.A430T on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as rs564953226; called by muse, mutect2, varscan2
- MTSS1 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.123); catalogued as rs759302505, COSV61497476; called by muse, mutect2, varscan2
- MVD | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as rs202128233, COSV55368649; called by muse, mutect2, varscan2
- MYBBP1A | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as rs766943097; called by muse, mutect2, varscan2
- MYDGF | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs200622596, COSV99501708; called by muse, mutect2, varscan2
- MYL2 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs369868176, CM1414569; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.5261G>A p.R1754H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs544020493, COSV52753726; called by muse, mutect2, varscan2
- MYO9A | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201188859; called by muse, mutect2, varscan2
- MYOF | c.5077G>A p.E1693K | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs745392257, COSV63701035; called by muse, mutect2, varscan2
- MZT2A | c.415A>G p.S139G | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1440937893; called by muse, mutect2, varscan2
- NAXD | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs531114784, COSV57287124; called by muse, mutect2, varscan2
- NBR1 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs901448924; called by muse, varscan2
- NDUFS7 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as rs754948521; called by muse, mutect2, varscan2
- NECAB3 | c.1106G>A p.R369H (on ENST00000246190 / NM_031232.4; = p.R335H on NM_031231.4) | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1249176303; called by muse, mutect2, varscan2
- NELFE | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.953); catalogued as rs566216256, COSV64812315; called by mutect2, varscan2
- NEUROG3 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54342335; called by muse, mutect2, varscan2
- NFATC2 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.933); catalogued as rs146383420; called by muse, mutect2, varscan2
- NFE2L3 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.198); catalogued as rs1442690843; called by muse, mutect2
- NKAPL | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV59197174; called by muse, mutect2, varscan2
- NKPD1 | c.1910A>T p.Q637L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.055); catalogued as rs749449338; called by muse, mutect2, varscan2
- NOC4L | c.868A>G p.M290V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs750161277; called by muse, varscan2
- NOTCH3 | c.747dup p.T250Dfs*10 | Frame Shift Ins (INS) | VAF 6/23 reads (26%) | catalogued as rs1412990396; called by mutect2, pindel, varscan2
- NPR1 | c.1603G>A p.G535R | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.048); catalogued as rs572340596, COSV64117502; called by muse, mutect2, varscan2
- NRAP | c.3807C>T p.D1269= (on ENST00000359988 / NM_001322945.2; = p.D1234= on NM_006175.4) | Splice Region (SNP) | VAF 18/77 reads (23%) | catalogued as rs777328884, COSV63491131; called by muse, mutect2, varscan2
- NRG2 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.021); catalogued as rs760899111; called by muse, mutect2, varscan2
- NTRK1 | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs745776726, COSV62324579; called by muse, mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | catalogued as rs760869296; called by mutect2, varscan2
- NUP43 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 25/92 reads (27%) | catalogued as rs147323573; called by muse, mutect2, varscan2
- NYAP2 | c.1004C>A p.P335Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56003313; called by muse, mutect2, varscan2
- OAS2 | c.1277dup p.N426Kfs*12 | Frame Shift Ins (INS) | VAF 18/69 reads (26%) | catalogued as rs781171419; called by mutect2, varscan2
- OBSCN | c.10038_10039dup p.G3347Vfs*20 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | catalogued as rs772869624; called by mutect2, varscan2
- OGDHL | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370076789; called by muse, mutect2, varscan2
- OR10G4 | c.731G>A p.C244Y | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57977364; called by muse, mutect2, varscan2
- OR4C16 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199938003, COSV58942583; called by muse, mutect2, varscan2
- OR5AC2 | c.806C>A p.A269D | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as rs761364333; called by muse, mutect2, varscan2
- OR6C65 | c.305dup p.L102Ffs*18 | Frame Shift Ins (INS) | VAF 21/61 reads (34%) | catalogued as rs753853776; called by mutect2, varscan2
- OR7E24 | c.504del p.F168Lfs*12 | Frame Shift Del (DEL) | VAF 27/98 reads (28%) | catalogued as rs1031417078; called by mutect2, pindel, varscan2
- OR8H1 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100477167; called by muse, mutect2, varscan2
- OSBPL7 | c.2362C>T p.R788* | Nonsense Mutation (SNP) | VAF 16/28 reads (57%) | catalogued as rs770983052, COSV50106606; called by muse, mutect2, varscan2
- P2RY12 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.241); catalogued as COSV56383303; called by muse, mutect2, varscan2
- PAQR6 | c.965G>A p.R322Q (on ENST00000292291 / NM_001272108.2; = p.G240R on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs564476902; called by muse, mutect2, varscan2
- PARD6G | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs750051978, COSV62060314; called by muse, mutect2, varscan2
- PATZ1 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as rs1365539466; called by muse, mutect2, varscan2
- PCDHA10 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.029); catalogued as COSV56504438; called by muse, mutect2, varscan2
- PCDHA12 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV99166150; called by muse, mutect2, varscan2
- PCDHB16 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as rs782583100, COSV53366442; called by muse, mutect2, varscan2
- PCDHGA8 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.094); catalogued as rs141295392; called by muse, mutect2, varscan2
- PCLO | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61653297; called by muse, mutect2, varscan2
- PDCD6 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373052818, COSV53776846; called by muse, mutect2, varscan2
- PFKFB4 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 28/46 reads (61%) | PolyPhen possibly damaging (0.767); catalogued as rs550543115; called by muse, mutect2, varscan2
- PHLDB3 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1428651958; called by muse, mutect2, varscan2
- PHRF1 | c.3256C>T p.R1086W (on ENST00000264555 / NM_001286581.2; = p.R1085W on NM_020901.4) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs375916304; called by muse, mutect2, varscan2
- PI4KA | c.5116+1G>A p.X1706_splice | Splice Site (SNP) | VAF 23/81 reads (28%) | catalogued as rs773697738; called by muse, mutect2, varscan2
- PIDD1 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61753929; called by muse, mutect2, varscan2
- PIK3R2 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs775277118; called by muse, mutect2, varscan2
- PIN4 | c.158C>T p.A53V (on ENST00000664196; = p.A28V on NM_006223.4) | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1213489459; called by muse, varscan2
- PIP5K1C | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs368769937, COSV58954774; called by muse, mutect2, varscan2
- PJA1 | c.1276G>A p.G426R (on ENST00000361478 / NM_145119.4; = p.G238R on NM_022368.5) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.07); catalogued as COSV100824795, COSV64053977; called by muse, mutect2, varscan2
- PKD1 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 73/251 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.259); catalogued as rs777873071; called by muse, mutect2, varscan2
- PLA2G15 | c.1025_1027del p.F342del | In Frame Del (DEL) | VAF 5/31 reads (16%) | catalogued as rs749899569; called by mutect2, pindel, varscan2
- PLCB1 | c.781A>G p.I261V | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0.017); catalogued as rs1568549591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHG4 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs752568542; called by muse, mutect2, varscan2
- PLEKHG4 | c.2315G>A p.R772H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765749525, COSV58571329; called by mutect2, varscan2
- PLEKHG5 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.535); catalogued as rs373594469; called by muse, mutect2, varscan2
- PLEKHG6 | c.1862_1864del p.F621del | In Frame Del (DEL) | VAF 28/110 reads (25%) | catalogued as rs1285349538; called by mutect2, pindel, varscan2
- PLXNB1 | c.4372_4373del p.L1458Afs*2 | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | catalogued as rs1164681397; called by mutect2, pindel, varscan2
- PLXNB3 | c.1789C>T p.H597Y | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV62802253; called by muse, mutect2, varscan2
- PMS1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.479); catalogued as rs183717609; called by muse, mutect2, varscan2
- POLA1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1313362497; called by muse, mutect2, varscan2
- POLRMT | c.1970C>T p.S657L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs760917021, COSV52114429; called by muse, varscan2
- PPP1R12B | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs753256240, COSV99295181; called by muse, mutect2, varscan2
- PPP1R26 | c.2692del p.V898Sfs*56 | Frame Shift Del (DEL) | VAF 15/72 reads (21%) | catalogued as rs1365223299; called by mutect2, varscan2
- PPP1R3A | c.3001G>A p.E1001K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99492399; called by muse, mutect2, varscan2
- PPP2R5D | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764831855, COSV55151522; called by muse, mutect2
- PRDM16 | c.2227C>T p.R743* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV99576524; called by muse, mutect2, varscan2
- PRDM2 | c.4773del p.K1591Nfs*23 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | catalogued as rs1435057935, COSV52454422; called by mutect2, pindel, varscan2
- PRPF39 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766400733; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 24/41 reads (59%) | catalogued as rs781858060; called by mutect2, varscan2
- PTCH2 | c.2303C>T p.A768V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.154); catalogued as rs761442845, COSV64709764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTGDR | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs138094600; called by muse, mutect2, varscan2
- PTPRN | c.2072C>T p.T691M | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542436411, COSV55351080; called by muse, mutect2, varscan2
- PTPRO | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as rs767153532, COSV99842220; called by muse, mutect2, varscan2
- PYGO1 | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs147078512; called by mutect2, varscan2
- RAI1 | c.4982G>A p.R1661Q | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.728); catalogued as rs1428571884; called by muse, mutect2, varscan2
- RALGAPB | c.1142dup p.H382Tfs*2 | Frame Shift Ins (INS) | VAF 32/84 reads (38%) | catalogued as rs756557178; called by mutect2, varscan2
- RAPGEF6 | c.3874C>T p.R1292W | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs770850083; called by muse, mutect2, varscan2
- RASA2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as rs944578775, COSV53938966; called by muse, mutect2, varscan2
- RASAL1 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs760009413, COSV55654107; called by muse, mutect2, varscan2
- RASD2 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV99332599; called by muse, varscan2
- RBBP8 | c.152+4_152+7del p.X51_splice | Splice Site (DEL) | VAF 15/65 reads (23%) | catalogued as rs1272130787; called by mutect2, pindel, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | catalogued as rs762006287; called by mutect2, varscan2
- RBPJL | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767768517, COSV59214043; called by muse, mutect2, varscan2
- RDM1 | c.799T>C p.Y267H | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.37); PolyPhen benign (0.365); catalogued as rs1246615243; called by muse, mutect2, varscan2
- RELB | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.08); catalogued as rs1452443919; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs751982308; called by mutect2, varscan2
- RMC1 | c.1097T>C p.I366T | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs776428067; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 30/102 reads (29%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- ROBO1 | c.3971C>T p.T1324M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1045339363, COSV71392720, COSV71397929; called by muse, mutect2, varscan2
- ROBO2 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs765218623, COSV59936575; called by muse, mutect2, varscan2
- RPGRIP1L | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs1296403401, COSV50902601; called by muse, mutect2, varscan2
- RPL15 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.159); catalogued as rs1398566766; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS9 | c.573G>C p.E191D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs753325379, COSV57189471; called by muse, mutect2, varscan2
- SALL4 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs374255657; called by muse, mutect2, varscan2
- SCAF4 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 44/92 reads (48%) | catalogued as rs1439594249, COSV54584476, COSV54585696; called by muse, mutect2, varscan2
- SCYL1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs573532447, COSV54212313; called by muse, mutect2, varscan2
- SDK2 | c.4217C>T p.P1406L | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs909729322; called by muse, mutect2, varscan2
- SEMG2 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs772703748, COSV65647631; called by muse, mutect2, varscan2
- SERINC3 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.717); catalogued as rs760064770, COSV54856683; called by muse, mutect2, varscan2
- SF1 | c.1713dup p.G572Rfs*40 | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | catalogued as rs1339885388; called by pindel, varscan2
- SGSM1 | c.2885G>A p.R962H (on ENST00000400359 / NM_001039948.4; = p.R901H on NM_133454.3) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs762180950; called by muse, mutect2, varscan2
- SH3BP5L | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1214579112, COSV63539337; called by muse, mutect2
- SIGLEC10 | c.2023G>A p.V675I | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as rs778335635, COSV59479484; called by muse, mutect2, varscan2
- SIGLEC12 | c.915dup p.T306Hfs*136 (on ENST00000291707 / NM_053003.4; = p.T188Hfs*136 on NM_033329.2) | Frame Shift Ins (INS) | VAF 9/47 reads (19%) | catalogued as rs758011625; called by mutect2, pindel, varscan2
- SIN3B | c.3473G>A p.R1158H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.673); catalogued as rs775623591; called by muse, varscan2
- SIPA1L3 | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs759396588; called by mutect2, varscan2
- SLC10A6 | c.260C>A p.A87D | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV56721653; called by muse, mutect2, varscan2
- SLC20A2 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs997050954; called by muse, mutect2, varscan2
- SLC22A10 | c.954+2T>C p.X318_splice | Splice Site (SNP) | VAF 24/106 reads (23%) | catalogued as rs1031959746; called by muse, mutect2, varscan2
- SLC26A7 | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs766666333; called by muse, varscan2
- SLC27A4 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.893); catalogued as rs780754811, COSV55960072; called by muse, mutect2, varscan2
- SLC34A2 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1215136729, COSV65940887; called by muse, mutect2, varscan2
- SLC39A4 | c.1021G>A p.A341T (on ENST00000301305 / NM_001374839.1; = p.A316T on NM_017767.3) | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs781822449; called by muse, mutect2, varscan2
- SLC6A3 | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.345); catalogued as rs141740642; called by muse, mutect2, varscan2
- SLC7A4 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as rs759478605, COSV60384776; called by muse, mutect2, varscan2
- SLCO5A1 | c.1555del p.S519Qfs*13 | Frame Shift Del (DEL) | VAF 46/134 reads (34%) | catalogued as COSV52664854; called by mutect2, varscan2
- SMPD1 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as rs370198638; called by muse, mutect2, varscan2
- SOGA1 | c.2357T>C p.I786T | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as rs961023968; called by muse, mutect2, varscan2
- SPATA13 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs754726668; called by muse, mutect2, varscan2
- SPEN | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471081719, COSV104424589, COSV65361349; called by muse, mutect2, varscan2
- SPTBN4 | c.5120G>A p.R1707H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747837833, COSV100151865, COSV58956566; called by muse, mutect2, varscan2
- SPTLC1 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs371203080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRCAP | c.8165G>A p.R2722H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs563906113; called by muse, varscan2
- SRCAP | c.8303G>A p.R2768Q | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs748197121, COSV52668483; called by muse, varscan2
- SSH1 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as rs139497269; called by muse, mutect2, varscan2
- SSH2 | c.3901G>A p.A1301T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs533970239, COSV99282499; called by muse, mutect2, varscan2
- ST6GAL1 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 11/85 reads (13%) | PolyPhen probably damaging (1); catalogued as rs763097294, COSV51470420; called by muse, mutect2, varscan2
- STARD13 | c.2132G>A p.R711H (on ENST00000336934 / NM_001243476.3; = p.R593H on NM_052851.3) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781620333; called by muse, mutect2, varscan2
- STK24 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1400122531; called by muse, mutect2, varscan2
- SV2A | c.374dup p.S127Efs*2 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs1167154522; called by mutect2, varscan2
- SV2B | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs372020741; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | catalogued as rs570102997; called by mutect2, varscan2
- SYNE1 | c.7041del p.E2348Nfs*35 (on ENST00000367255 / NM_182961.4; = p.E2355Nfs*35 on NM_033071.3) | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | catalogued as rs1209016698; called by mutect2, pindel, varscan2
- TANC1 | c.3319C>T p.R1107W | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); catalogued as rs764599245, COSV55091944; called by muse, mutect2, varscan2
- TBC1D16 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.121); catalogued as rs373445911; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 28/58 reads (48%) | catalogued as rs763321097; called by mutect2, varscan2
- TELO2 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs752263174, COSV51982154; called by muse, mutect2, varscan2
- TENM1 | c.5348C>T p.S1783L | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1231294323, COSV64428194; called by muse, mutect2, varscan2
- THADA | c.4670G>A p.R1557H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs759472606; called by muse, mutect2, varscan2
- THSD4 | c.2453C>T p.S818L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs766502435; called by muse, mutect2, varscan2
- TICRR | c.5525G>A p.S1842N | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV51543923; called by muse, mutect2, varscan2
- TLCD3B | c.28dup p.V10Gfs*59 | Frame Shift Ins (INS) | VAF 32/160 reads (20%) | catalogued as rs780301705; called by mutect2, varscan2
- TMEM250 | c.177_181del p.Y59* | Nonsense Mutation (DEL) | VAF 18/67 reads (27%) | catalogued as rs763382232; called by mutect2, pindel, varscan2
- TMEM41B | c.722_724del p.S241del | In Frame Del (DEL) | VAF 16/65 reads (25%) | catalogued as rs1312701218; called by pindel, varscan2
- TMEM63A | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as rs763382932, COSV64763130; called by muse, mutect2, varscan2
- TMEM63B | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1444104814; called by muse, mutect2, varscan2
- TRAPPC9 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs376505164, COSV66906752, COSV66906757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 38/113 reads (34%) | catalogued as rs752676391; called by mutect2, varscan2
- TRO | c.2932A>G p.S978G | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs926128991; called by muse, varscan2
- TRPM5 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs895936733; called by muse, mutect2, varscan2
- TSBP1 | c.670del p.S224Lfs*8 (on ENST00000617061; = p.S227Lfs*8 on NM_006781.5) | Frame Shift Del (DEL) | VAF 58/133 reads (44%) | catalogued as COSV66660771; called by mutect2, varscan2
- TSR1 | c.2198C>T p.T733M | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200320130; called by muse, mutect2, varscan2
- TTC38 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as rs763753465; called by muse, mutect2, varscan2
- TTLL11 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as rs781081624, COSV100388813; called by muse, mutect2, varscan2
- TTN | c.56708A>G p.H18903R (on ENST00000591111; = p.H11479R on NM_003319.4) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | PolyPhen probably damaging (0.943); catalogued as rs876658073, COSV59871912; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | catalogued as rs760251146; called by mutect2, varscan2
- UBAP2L | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs762626219, COSV99672681; called by muse, mutect2, varscan2
- UBAP2L | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs369170828; called by muse, mutect2, varscan2
- UBASH3A | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs200787839; called by muse, mutect2, varscan2
- UBR5 | c.2500G>A p.D834N | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.959); catalogued as rs1425681050; called by muse, mutect2, varscan2
- UNC5D | c.2860T>C p.*954Qext*9 | Nonstop Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV54820352; called by muse, mutect2, varscan2
- UNC79 | c.1411C>T p.R471W (on ENST00000393151 / NM_001346218.2; = p.R294W on NM_020818.5) | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56418190; called by muse, mutect2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | catalogued as rs767420916; called by mutect2, varscan2
- UROC1 | c.920del p.K307Rfs*77 | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | catalogued as rs754361807; called by mutect2, varscan2
- USP40 | c.3441del p.K1147Nfs*12 | Frame Shift Del (DEL) | VAF 38/116 reads (33%) | catalogued as rs572063854; called by mutect2, varscan2
- UVRAG | c.709del p.S237Vfs*6 | Frame Shift Del (DEL) | VAF 25/68 reads (37%) | catalogued as rs762976381; called by mutect2, varscan2
- VAV1 | c.2465G>A p.R822Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1208856602, COSV58380014, COSV58390550; called by muse, mutect2, varscan2
- VEZT | c.220del p.S74Lfs*38 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | catalogued as rs748321397; called by mutect2, varscan2
- VWCE | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs755876996, COSV57112739; called by muse, mutect2, varscan2
- WASL | c.20A>C p.Q7P | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs779588397, COSV56135437; called by muse, mutect2, varscan2
- WDR5 | c.648dup p.V217Rfs*42 | Frame Shift Ins (INS) | VAF 62/126 reads (49%) | catalogued as rs780890680; called by mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | catalogued as rs746919573; called by mutect2, varscan2
- XAGE3 | c.162_164del p.E54del | In Frame Del (DEL) | VAF 30/67 reads (45%) | catalogued as rs781916947; called by pindel, varscan2
- XPO7 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV53013911; called by muse, mutect2, varscan2
- YY2 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV63410760; called by muse, mutect2, varscan2
- ZBTB21 | c.1888_1889dup p.I631Kfs*6 | Frame Shift Ins (INS) | VAF 16/36 reads (44%) | catalogued as rs769060928; called by mutect2, varscan2
- ZC3H7B | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60960824; called by muse, mutect2, varscan2
- ZFYVE16 | c.3778C>T p.R1260W | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs373776472; called by muse, mutect2, varscan2
- ZNF124 | c.1051del p.M351Cfs*19 (on ENST00000543802 / NM_001297568.1; = p.M289Cfs*19 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | catalogued as rs755727997; called by mutect2, pindel, varscan2
- ZNF462 | c.4540G>A p.V1514I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs780560264; called by muse, mutect2, varscan2
- ZNF493 | c.1930_1931del p.V644Tfs*35 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | catalogued as rs765411401; called by mutect2, pindel, varscan2
- ZNF559 | c.212dup p.L71Ffs*22 | Frame Shift Ins (INS) | VAF 14/55 reads (25%) | catalogued as rs747265027; called by mutect2, pindel, varscan2
- ZNF609 | c.812A>G p.N271S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs751950908, COSV58589736; called by muse, mutect2, varscan2
- ZNF626 | c.513dup p.P172Tfs*12 | Frame Shift Ins (INS) | VAF 44/194 reads (23%) | catalogued as rs782384330; called by mutect2, pindel, varscan2
- ZNF710 | c.744G>A p.W248* | Nonsense Mutation (SNP) | VAF 36/118 reads (31%) | catalogued as rs779442464; called by muse, mutect2, varscan2
- ZNF710 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99184147; called by muse, mutect2
- ZNF827 | c.3047A>T p.E1016V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV101061619; called by muse, mutect2, varscan2
- ZNF831 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV64045192; called by muse, mutect2, varscan2
- ZRANB3 | c.1597del p.R533Dfs*3 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs765112091; called by mutect2, pindel, varscan2
- ZWINT | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs754852712, COSV59184784; called by muse, mutect2, varscan2
- ABCA2 | c.2008C>T p.R670C (on ENST00000614293; = p.R640C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA4 | c.4616C>A p.P1539H | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ABHD14B | c.408del p.I137Sfs*14 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- ACE | c.1188G>T p.Q396H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ADAMTS2 | c.3418del p.L1140Wfs*22 | Frame Shift Del (DEL) | VAF 37/107 reads (35%) | called by mutect2, pindel, varscan2
- ADNP2 | c.334_335del p.V112Ifs*32 | Frame Shift Del (DEL) | VAF 24/83 reads (29%) | called by pindel, varscan2
- ADORA3 | c.721_722del p.L241Vfs*15 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by pindel, varscan2
- ADSS2 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- AFG3L2 | c.255del p.A86Lfs*99 | Frame Shift Del (DEL) | VAF 21/98 reads (21%) | called by mutect2, pindel, varscan2
- AGAP1 | c.326_329del p.K109Rfs*12 | Frame Shift Del (DEL) | VAF 46/151 reads (30%) | called by pindel, varscan2
- AGO2 | c.1065del p.K355Nfs*2 | Frame Shift Del (DEL) | VAF 34/96 reads (35%) | called by mutect2, pindel, varscan2
- AKNA | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- ALG10 | c.886del p.S296Hfs*23 | Frame Shift Del (DEL) | VAF 34/138 reads (25%) | called by mutect2, pindel, varscan2
- ALOX12 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ALPK1 | c.2800T>C p.S934P | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ANK2 | c.73del p.R25Dfs*27 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.850T>A p.L284I | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ANKRD12 | c.1373dup p.E459Gfs*7 | Frame Shift Ins (INS) | VAF 24/127 reads (19%) | called by mutect2, pindel, varscan2
- ANKRD24 | c.975G>T p.E325D | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- APBA3 | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- APBB1IP | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); called by muse, mutect2
- ARHGAP5 | c.2828del p.N943Ifs*2 | Frame Shift Del (DEL) | VAF 28/87 reads (32%) | called by mutect2, varscan2
- ARHGEF6 | c.92del p.L31* | Frame Shift Del (DEL) | VAF 51/105 reads (49%) | called by mutect2, pindel, varscan2
- ARID1A | c.4555del p.Q1519Rfs*8 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- AUH | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | called by pindel, varscan2
- BAG3 | c.1125_1127del p.P376del | In Frame Del (DEL) | VAF 14/52 reads (27%) | called by pindel, varscan2
- BAZ1B | c.976T>G p.S326A | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCL2L2-PABPN1 | c.*5del | Frame Shift Del (DEL) | VAF 16/115 reads (14%) | called by mutect2, pindel, varscan2
- BEND3 | c.2073del p.E692Rfs*141 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by pindel, varscan2
- BMP7 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.122); called by muse, mutect2
- BPIFA2 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BUB1B | c.1508G>A p.C503Y | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C1QL4 | c.242del p.P81Qfs*52 | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- C2orf69 | c.359A>G p.H120R | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2
- CANT1 | c.287del p.P96Hfs*34 | Frame Shift Del (DEL) | VAF 80/166 reads (48%) | called by mutect2, pindel, varscan2
- CAPS | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CASP7 | c.271_274del p.D91Kfs*17 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- CBX4 | c.690del p.N231Tfs*3 | Frame Shift Del (DEL) | VAF 19/43 reads (44%) | called by mutect2, pindel, varscan2
- CBX6 | c.425del p.G142Afs*23 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- CCDC34 | c.113C>G p.T38R | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CCPG1 | c.1403del p.K468Rfs*29 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel
- CCPG1 | c.1265del p.K422Rfs*3 | Frame Shift Del (DEL) | VAF 22/97 reads (23%) | called by mutect2, pindel, varscan2
- CDK11B | c.1839G>T p.K613N | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CELSR1 | c.4805del p.G1602Vfs*104 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | called by mutect2, varscan2
- CEP350 | c.4524_4525del p.Q1509Efs*2 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | called by pindel, varscan2
- CEP85 | c.56-1G>T p.X19_splice | Splice Site (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2, varscan2
- CFAP65 | c.1384+2T>C p.X462_splice | Splice Site (SNP) | VAF 21/83 reads (25%) | called by muse, mutect2, varscan2
- CHD8 | c.898dup p.Q300Pfs*121 (on ENST00000646647 / NM_001170629.2; = p.Q21Pfs*121 on NM_020920.4) | Frame Shift Ins (INS) | VAF 27/92 reads (29%) | called by mutect2, pindel, varscan2
- CHGB | c.23G>T p.S8I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by mutect2, varscan2
- CHRDL2 | c.12G>T p.E4D | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRM1 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- CHRNB3 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- CKAP2 | c.482C>T p.T161I (on ENST00000378037 / NM_001098525.2; = p.T160I on NM_018204.5) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- CKAP5 | c.5060C>T p.A1687V (on ENST00000529230 / NM_001008938.4; = p.A1627V on NM_014756.3) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- CLDN25 | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- CMIP | c.1449dup p.K484Qfs*7 (on ENST00000537098 / NM_198390.2; = p.K390Qfs*7 on NM_030629.3) | Frame Shift Ins (INS) | VAF 29/88 reads (33%) | called by mutect2, pindel, varscan2
- CMYA5 | c.9461G>T p.G3154V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTFR | c.290T>G p.L97R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTN4 | c.1511del p.P504Lfs*18 | Frame Shift Del (DEL) | VAF 15/111 reads (14%) | called by mutect2, pindel, varscan2
- COL4A4 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL9A2 | c.113dup p.P40Tfs*13 | Frame Shift Ins (INS) | VAF 29/155 reads (19%) | called by mutect2, pindel, varscan2
- CPNE4 | c.719A>G p.D240G | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CRACD | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DCAF4L2 | c.965T>C p.V322A | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- DCTN1 | c.2381T>C p.I794T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- DDC | c.1297del p.I433Sfs*98 | Frame Shift Del (DEL) | VAF 33/105 reads (31%) | called by mutect2, pindel, varscan2
- DDX51 | c.1750del p.Q584Sfs*3 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, varscan2
- DENND2A | c.1777A>C p.K593Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DENND4A | c.5080_5083del p.S1694Lfs*23 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by pindel, varscan2
- DNAH5 | c.9938G>A p.G3313D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- DNAH8 | c.595A>G p.K199E | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2
- DPRX | c.338_339insA p.A114Cfs*30 | Frame Shift Ins (INS) | VAF 18/60 reads (30%) | called by mutect2, pindel*, varscan2
- DSC3 | c.1919dup p.N640Kfs*28 | Frame Shift Ins (INS) | VAF 41/115 reads (36%) | called by mutect2, pindel, varscan2
- DYNC1I2 | c.104_105del p.K35Rfs*19 | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | called by mutect2, varscan2
- DYNC2I2 | c.1171del p.H391Tfs*8 | Frame Shift Del (DEL) | VAF 40/187 reads (21%) | called by mutect2, pindel, varscan2
- EML1 | c.2357A>G p.H786R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- EPHA4 | c.2264A>C p.N755T | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ERICH3 | c.3202del p.T1068Hfs*3 | Frame Shift Del (DEL) | VAF 19/110 reads (17%) | called by mutect2, pindel, varscan2
- F13A1 | c.1698G>T p.K566N | Missense Mutation (SNP) | VAF 92/211 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- F13A1 | c.1273T>C p.F425L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAM133A | c.271del p.R91Efs*67 | Frame Shift Del (DEL) | VAF 24/46 reads (52%) | called by mutect2, varscan2
- FAM228A | c.320T>C p.F107S | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- FAM32A | c.86del p.K29Rfs*50 | Frame Shift Del (DEL) | VAF 20/89 reads (22%) | called by mutect2, pindel, varscan2
- FAT2 | c.4412A>G p.Q1471R | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- FBXO42 | c.2039C>T p.T680I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FLG | c.9072A>C p.E3024D | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FLT1 | c.166dup p.E56Gfs*5 | Frame Shift Ins (INS) | VAF 22/87 reads (25%) | called by mutect2, pindel, varscan2
- FRYL | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- GABRQ | c.1699G>T p.A567S | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GLUL | c.154_155del p.K52Vfs*7 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- GNB2 | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- GOLGA2 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPHN | c.787del p.L263Sfs*61 (on ENST00000315266 / NM_001377519.1; = p.L296Sfs*61 on NM_020806.5) | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- GPR12 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPSM3 | c.468dup p.T157Hfs*60 | Frame Shift Ins (INS) | VAF 14/128 reads (11%) | called by mutect2, varscan2
- GRINA | c.333del p.N112Tfs*56 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- GUCY2C | c.1963G>A p.A655T | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- HORMAD1 | c.276dup p.Y93Ifs*32 | Frame Shift Ins (INS) | VAF 31/158 reads (20%) | called by pindel, varscan2
- HOXD4 | c.711del p.S238Afs*15 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- HS3ST6 | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HTR6 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IGHG4 | c.315del p.C106Afs*27 | Frame Shift Del (DEL) | VAF 18/153 reads (12%) | called by mutect2, varscan2
- IGHG4 | c.314C>G p.P105R | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by mutect2, varscan2
- IL1RL2 | c.850del p.V284Wfs*15 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- IL2 | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ISG15 | c.496T>C p.*166Qext*? | Nonstop Mutation (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- JAG1 | c.1949_1951del p.S650del | In Frame Del (DEL) | VAF 16/93 reads (17%) | called by mutect2, pindel, varscan2
- JARID2 | c.176_177del p.V59Efs*6 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | called by pindel, varscan2
- KATNBL1 | c.394del p.Q132Rfs*32 | Frame Shift Del (DEL) | VAF 31/111 reads (28%) | called by mutect2, pindel, varscan2
- KBTBD3 | c.1524C>A p.N508K | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KCNAB1 | c.731C>A p.A244D (on ENST00000490337 / NM_172160.3; = p.A233D on NM_003471.3) | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2
- KCNS1 | c.934T>A p.S312T | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KCTD8 | c.1185del p.A396Hfs*39 | Frame Shift Del (DEL) | VAF 19/156 reads (12%) | called by mutect2, pindel, varscan2
- KIAA1586 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KIF5C | c.1118_1120del p.X373_splice | Splice Site (DEL) | VAF 32/138 reads (23%) | called by mutect2, pindel, varscan2
- KLHL12 | c.1351G>A p.G451R | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KMT2D | c.16208G>A p.R5403H | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, varscan2
- KRCC1 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KRT83 | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA3 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- LCT | c.3968_3971del p.E1323Gfs*2 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | called by mutect2, pindel, varscan2
- LEFTY2 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- LGALS8 | c.8_10del p.L3del | In Frame Del (DEL) | VAF 31/83 reads (37%) | called by pindel, varscan2
- LRP1B | c.9814G>T p.V3272F | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP1B | c.8128G>T p.G2710* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- LRR1 | c.1164T>G p.N388K | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- LRRC4C | c.86T>G p.V29G | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- LRRC6 | c.590del p.N197Mfs*25 | Frame Shift Del (DEL) | VAF 38/233 reads (16%) | called by mutect2, pindel, varscan2
- LRRIQ4 | c.857A>G p.Y286C | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LRRK2 | c.73A>G p.N25D | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LVRN | c.623T>C p.F208S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- MAGEB10 | c.120dup p.S41Lfs*15 | Frame Shift Ins (INS) | VAF 24/61 reads (39%) | called by mutect2, pindel, varscan2
- MAGEC1 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K10 | c.877C>A p.L293M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MAP3K4 | c.2297dup p.L766Ffs*11 | Frame Shift Ins (INS) | VAF 16/89 reads (18%) | called by mutect2, pindel, varscan2
- MAPK8IP1 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MPC1 | c.127_129del p.D43del | In Frame Del (DEL) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- MRPS15 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MRTFB | c.761del p.P254Hfs*23 | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- MYLK | c.3788G>T p.G1263V | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCOR1 | c.1573dup p.T525Nfs*11 | Frame Shift Ins (INS) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- NDST3 | c.2074A>G p.T692A | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NEU1 | c.968T>C p.V323A | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- NID1 | c.3707A>G p.D1236G | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- NIN | c.5558G>T p.W1853L (on ENST00000382041 / NM_182946.1; = p.W1140L on NM_016350.4) | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- NME8 | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- NOD2 | c.683C>A p.T228N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- NOL10 | c.1948T>C p.S650P | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- NOS1AP | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- NPAS2 | c.2393del p.P798Qfs*40 | Frame Shift Del (DEL) | VAF 25/114 reads (22%) | called by mutect2, pindel, varscan2
- NPHP4 | c.710T>C p.I237T | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRDE2 | c.3063dup p.D1022* | Frame Shift Ins (INS) | VAF 14/123 reads (11%) | called by mutect2, pindel, varscan2
- NSD3 | c.3116del p.K1039Rfs*13 | Frame Shift Del (DEL) | VAF 8/104 reads (8%) | called by mutect2, pindel
- OPLAH | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 130/275 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- OR13A1 | c.421T>C p.Y141H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR52B6 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2
- OR52M1 | c.718del p.T240Pfs*13 | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | called by mutect2, pindel, varscan2
- OR5P3 | c.525T>A p.N175K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- OR9G4 | c.206dup p.L69Ffs*22 | Frame Shift Ins (INS) | VAF 21/99 reads (21%) | called by mutect2, pindel, varscan2
- P3H2 | c.1578G>C p.K526N | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PALD1 | c.2216C>A p.P739H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PANK1 | c.865C>T p.R289* (on ENST00000307534 / NM_148977.2; = p.R64* on NM_138316.4) | Nonsense Mutation (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- PARP10 | c.1680+2T>C p.X560_splice | Splice Site (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2, varscan2
- PBRM1 | c.402T>G p.Y134* | Nonsense Mutation (SNP) | VAF 38/66 reads (58%) | called by muse, varscan2
- PCDH12 | c.2052del p.L685Yfs*7 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- PCDHA9 | c.2238dup p.S747Efs*18 | Frame Shift Ins (INS) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- PCDHB15 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PDE8A | c.806del p.K269Rfs*8 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | called by mutect2, pindel, varscan2
- PDLIM2 | c.398G>A p.G133D (on ENST00000397760; = p.G383D on NM_021630.6) | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PDS5B | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- PDZRN3 | c.2011del p.L671Wfs*18 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
- PEAK1 | c.204del p.K68Nfs*4 | Frame Shift Del (DEL) | VAF 23/98 reads (23%) | called by mutect2, pindel, varscan2
- PGBD1 | c.2014G>T p.G672W | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIGG | c.412A>G p.N138D | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- PIK3C2A | c.2481dup p.G828Rfs*12 | Frame Shift Ins (INS) | VAF 49/148 reads (33%) | called by mutect2, pindel, varscan2
- PKDREJ | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- PLA2G7 | c.176del p.G59Efs*12 | Frame Shift Del (DEL) | VAF 24/136 reads (18%) | called by mutect2, pindel, varscan2
- PLAUR | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PLCE1 | c.5737C>T p.R1913* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- PLEK | c.988G>T p.A330S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- PLEKHA1 | c.1033dup p.Y345Lfs*28 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- PLEKHM1 | c.1944del p.E649Rfs*62 | Frame Shift Del (DEL) | VAF 39/88 reads (44%) | called by mutect2, pindel, varscan2
- PLK2 | c.1161_1162del p.R387Sfs*3 | Frame Shift Del (DEL) | VAF 10/106 reads (9%) | called by pindel, varscan2
- PLXNB2 | c.2844T>A p.C948* | Nonsense Mutation (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- POLN | c.2045A>G p.Y682C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POMGNT1 | c.982del p.V328Cfs*5 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- PRAM1 | c.1026dup p.R343Qfs*19 | Frame Shift Ins (INS) | VAF 23/82 reads (28%) | called by mutect2, pindel, varscan2
- PRDM13 | c.1505C>A p.P502H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRKDC | c.1926del p.F642Lfs*12 | Frame Shift Del (DEL) | VAF 62/169 reads (37%) | called by mutect2, pindel, varscan2
- PROX1 | c.1780del p.Y594Ifs*10 | Frame Shift Del (DEL) | VAF 27/113 reads (24%) | called by mutect2, pindel, varscan2
- PRPF18 | c.621_623del p.E207del | In Frame Del (DEL) | VAF 21/102 reads (21%) | called by pindel, varscan2
- PTBP3 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- RAB22A | c.432del p.F144Lfs*2 | Frame Shift Del (DEL) | VAF 48/175 reads (27%) | called by mutect2, pindel, varscan2
- RANBP3 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.633); called by muse, varscan2
- RBM44 | c.303_304del p.Q102Nfs*6 (on ENST00000611254; = p.Q736Nfs*6 on NM_001080504.2) | Frame Shift Del (DEL) | VAF 26/100 reads (26%) | called by pindel, varscan2
- RERE | c.248del p.K83Sfs*12 | Frame Shift Del (DEL) | VAF 28/115 reads (24%) | called by mutect2, varscan2
- RP1 | c.2377del p.R793Efs*55 | Frame Shift Del (DEL) | VAF 31/115 reads (27%) | called by mutect2, pindel, varscan2
- SAMSN1 | c.208del p.M70* | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- SCEL | c.1120A>G p.I374V (on ENST00000349847 / NM_144777.3; = p.I354V on NM_003843.4) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEC16A | c.4106G>A p.S1369N | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SEC24D | c.880C>A p.L294M | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SEMA5B | c.2713del p.Q905Rfs*147 | Frame Shift Del (DEL) | VAF 32/139 reads (23%) | called by mutect2, pindel, varscan2
- SEMA6A | c.2690A>G p.Q897R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.69); called by mutect2, varscan2
- SENP6 | c.1871A>C p.Q624P | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- SH3BP4 | c.1419del p.V474Sfs*18 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | called by mutect2, varscan2
- SKA3 | c.607del p.T203Lfs*6 | Frame Shift Del (DEL) | VAF 14/117 reads (12%) | called by mutect2, pindel, varscan2
- SLC2A2 | c.734A>G p.Y245C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC35C2 | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35D3 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SLC38A3 | c.732del p.N245Tfs*15 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | called by mutect2, pindel, varscan2
- SLC44A3 | c.1781del p.F594Sfs*26 (on ENST00000271227 / NM_001114106.3; = p.F546Sfs*26 on NM_152369.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/147 reads (21%) | called by mutect2, pindel, varscan2
- SLC6A6 | c.127A>G p.K43E | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SOX3 | c.427A>G p.M143V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SPX | c.305del p.N102Tfs*23 | Frame Shift Del (DEL) | VAF 37/146 reads (25%) | called by mutect2, pindel, varscan2
- SSH1 | c.463G>T p.G155* | Nonsense Mutation (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- STPG3 | c.187_189del p.E63del | In Frame Del (DEL) | VAF 21/120 reads (18%) | called by mutect2, pindel, varscan2
- TAAR1 | c.538G>T p.G180* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- TACC1 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TACR2 | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D23 | c.11_13del p.G4del | In Frame Del (DEL) | VAF 9/82 reads (11%) | called by mutect2, pindel, varscan2
- TBX18 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.122); called by muse, mutect2
- TCTE1 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- TEX44 | c.1091T>C p.V364A | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- TEX55 | c.920A>G p.H307R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- TFAP2D | c.1055T>C p.L352S | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TGFBR3 | c.2180A>G p.D727G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- THAP12 | c.163_165del p.Y55del | In Frame Del (DEL) | VAF 26/94 reads (28%) | called by mutect2, pindel, varscan2
- TIGD3 | c.394_396del p.N132del | In Frame Del (DEL) | VAF 20/68 reads (29%) | called by pindel, varscan2
- TLN2 | c.557del p.G186Efs*2 | Frame Shift Del (DEL) | VAF 15/98 reads (15%) | called by mutect2, pindel, varscan2
- TMC2 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TMEM132D | c.618del p.T207Rfs*75 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- TMEM199 | c.142T>A p.S48T | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2
- TMEM30B | c.605A>G p.Y202C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- TMPRSS15 | c.386A>C p.Q129P | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- TMPRSS9 | c.2168del p.G723Afs*18 (on ENST00000648592; = p.G689Afs*18 on NM_182973.2) | Frame Shift Del (DEL) | VAF 31/128 reads (24%) | called by mutect2, pindel, varscan2
- TNXB | c.5776dup p.E1926Gfs*20 (on ENST00000647633; = p.E1679Gfs*20 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 8/70 reads (11%) | called by mutect2, varscan2
- TRAM1L1 | c.1033del p.R345Efs*14 | Frame Shift Del (DEL) | VAF 27/106 reads (25%) | called by mutect2, pindel, varscan2
- TRIM8 | c.299del p.P100Rfs*95 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- TRO | c.2933G>A p.S978N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.175); called by muse, varscan2
- TSEN54 | c.1389_1391del p.K463del | In Frame Del (DEL) | VAF 24/51 reads (47%) | called by mutect2, pindel, varscan2
- TSHZ3 | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- TTN | c.34608G>A p.V11536= (on ENST00000591111; = p.V10609= on NM_133378.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 86/293 reads (29%) | called by muse, mutect2, varscan2
- TXNDC15 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBAP2 | c.1102del p.M368Wfs*13 | Frame Shift Del (DEL) | VAF 22/111 reads (20%) | called by mutect2, pindel, varscan2
- UBR1 | c.4745dup p.N1582Kfs*8 | Frame Shift Ins (INS) | VAF 17/60 reads (28%) | called by mutect2, varscan2
- UTP3 | c.118del p.D40Tfs*9 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- VEGFC | c.820G>C p.D274H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- VPS13A | c.8653del p.Y2885Mfs*20 | Frame Shift Del (DEL) | VAF 37/244 reads (15%) | called by mutect2, pindel, varscan2
- VPS13B | c.8693C>A p.A2898E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- VPS39 | c.176G>T p.C59F (on ENST00000348544 / NM_001301138.2; = p.C48F on NM_015289.5) | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.042); called by muse, mutect2
- VWA3B | c.3061G>A p.G1021R | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- VWA5A | c.120G>T p.E40D | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- WDR17 | c.3083G>A p.S1028N | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZBTB11 | c.2031G>T p.K677N | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZBTB11 | c.526T>C p.S176P | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ZDHHC12 | c.127del p.E43Sfs*30 | Frame Shift Del (DEL) | VAF 12/109 reads (11%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.7271_7272del p.E2424Gfs*4 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | called by pindel, varscan2
- ZFP1 | c.936_938del p.I313del | In Frame Del (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- ZFX | c.2065del p.M689Cfs*17 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | called by mutect2, pindel, varscan2
- ZFYVE9 | c.3940-1G>T p.X1314_splice | Splice Site (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- ZNF23 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- ZNF296 | c.1118del p.K373Rfs*29 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- ZNF639 | c.22del p.R8Efs*17 | Frame Shift Del (DEL) | VAF 68/155 reads (44%) | called by mutect2, pindel, varscan2
- ZNF777 | c.1969A>G p.T657A | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF780B | c.2499del p.*834Efs*4 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | called by mutect2, pindel, varscan2
- ACTRT1 | c.552A>T p.A184= | Silent (SNP) | VAF 59/96 reads (61%) | called by muse, mutect2, varscan2
- ADAM33 | c.2232G>A p.A744= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs776070426, COSV62934926; called by muse, mutect2, varscan2
- ADAMTS9 | c.4140C>T p.S1380= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as rs1339140729, COSV55780204; called by muse, mutect2, varscan2
- ADRB1 | c.483C>A p.T161= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- AGXT2 | c.1344C>T p.S448= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs751396943; called by muse, mutect2, varscan2
- AK8 | c.477A>G p.R159= | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as rs985827010; called by muse, mutect2, varscan2
- ANKIB1 | c.2661G>A p.A887= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs754689833; called by muse, mutect2, varscan2
- ANKRD50 | c.1083C>T p.C361= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV72386184; called by muse, mutect2, varscan2
- ANKS1A | c.2949G>A p.L983= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs986972999; called by muse, mutect2, varscan2
- ANO2 | c.2580G>A p.T860= (on ENST00000356134 / NM_001278597.3; = p.T864= on NM_001278596.3) | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as rs747591646, COSV59037160; called by muse, mutect2, varscan2
- ATF1 | c.27G>A p.T9= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as rs760384514; called by muse, mutect2, varscan2
- ATP6V0D2 | c.687C>A p.G229= | Silent (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- ATP9B | c.2346C>T p.L782= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs1229007584; called by muse, mutect2, varscan2
- B3GAT1 | c.352C>T p.L118= | Silent (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- BCL11B | c.2535G>A p.T845= (on ENST00000357195 / NM_001282237.2; = p.T774= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- BCL11B | c.735C>A p.G245= (on ENST00000357195 / NM_001282237.2; = p.G174= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- BCL9 | c.2619A>G p.S873= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs782329995; called by muse, mutect2, varscan2
- BMP7 | c.285C>G p.G95= | Silent (SNP) | VAF 12/145 reads (8%) | called by muse, mutect2
- BRINP3 | c.1584C>T p.S528= | Silent (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- C11orf42 | c.621G>A p.V207= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV56411139; called by muse, mutect2
- C2 | c.552G>A p.T184= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as rs1225743248, COSV54959683; called by muse, mutect2, varscan2
- C2CD3 | c.5809C>T p.L1937= | Silent (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- CA3 | c.606C>T p.C202= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs370798274; called by muse, mutect2, varscan2
- CACNA1D | c.5946C>A p.A1982= (on ENST00000350061 / NM_001128840.3; = p.A2002= on NM_000720.4) | Silent (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- CACNA1S | c.3090C>T p.D1030= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs766639108; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CACNG1 | c.30C>T p.R10= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs1161330865, COSV56826689; called by muse, mutect2, varscan2
- CAPRIN2 | c.1812T>C p.G604= | Silent (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- CASZ1 | c.96C>T p.N32= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs762459217; called by muse, mutect2, varscan2
- CAVIN4 | c.306T>C p.D102= | Silent (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- CBY2 | c.807G>A p.A269= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100137411, COSV100137820; called by muse, mutect2, varscan2
- CCDC171 | c.3501G>A p.A1167= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as rs375368358; called by muse, mutect2, varscan2
- CD80 | c.426C>T p.F142= | Silent (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- CDCP2 | c.753C>T p.Y251= | Silent (SNP) | VAF 32/117 reads (27%) | called by muse, mutect2, varscan2
- CDH1 | c.303C>T p.Y101= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs150789339; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- CDH3 | c.2370G>A p.A790= | Silent (SNP) | VAF 49/127 reads (39%) | catalogued as rs533035937, COSV99868373; called by muse, mutect2, varscan2
- CENPE | c.1803A>G p.Q601= | Silent (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- CENPF | c.4935A>G p.L1645= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1160147492, COSV65279601; called by muse, mutect2
- CFAP43 | c.1518A>G p.S506= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- CLCN6 | c.1704G>T p.G568= | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- CLNS1A | c.69T>G p.T23= | Silent (SNP) | VAF 32/146 reads (22%) | called by muse, mutect2, varscan2
- COL20A1 | c.3375C>T p.P1125= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs547372435; called by muse, mutect2, varscan2
- COL22A1 | c.3036G>C p.G1012= | Silent (SNP) | VAF 17/159 reads (11%) | called by muse, mutect2, varscan2
- COL5A1 | c.1920C>T p.G640= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as rs781663334; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A2 | c.1263C>T p.G421= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as rs778836612, COSV100154537; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.2265G>T p.V755= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV62023927; called by muse, mutect2, varscan2
- CREB5 | c.384C>T p.N128= (on ENST00000357727 / NM_182898.4; = p.N121= on NM_004904.3) | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs199608009, COSV63217204; called by muse, mutect2, varscan2
- CRTC1 | c.1833C>T p.H611= | Silent (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- DAB1 | c.1011C>T p.G337= (on ENST00000371231; = p.G304= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs1482139714, COSV100976322, COSV64691347; called by muse, mutect2, varscan2
- DENND4B | c.4437C>T p.P1479= | Silent (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- DHX37 | c.15C>T p.R5= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- DHX38 | c.696G>A p.S232= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs556379177; called by muse, mutect2, varscan2
- DMBT1 | c.7149C>T p.D2383= (on ENST00000338354 / NM_001377530.1; = p.D1626= on NM_004406.3) | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs749231034, COSV57533611; called by muse, mutect2, varscan2
- DMRT2 | c.75C>T p.D25= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs1452011848; called by muse, mutect2, varscan2
- DNMT1 | c.411G>A p.T137= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as rs369311643; called by muse, mutect2, varscan2
- EGFR | c.3369A>G p.P1123= | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- EIF3I | c.906C>T p.G302= (on ENST00000373586; = p.G304= on NM_003757.3) | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs183648795; called by muse, mutect2, varscan2
- ERAP2 | c.1773C>A p.T591= | Silent (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- FAM135A | c.2673T>A p.T891= (on ENST00000370479 / NM_001351599.1; = p.T678= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 57/106 reads (54%) | called by muse, mutect2, varscan2
- FAM222A | c.996C>T p.G332= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs1444935742; called by muse, mutect2
- FAM90A1 | c.837C>T p.G279= | Silent (SNP) | VAF 80/322 reads (25%) | catalogued as rs201435525, COSV56713789; called by muse, mutect2, varscan2
- FARP2 | c.1110C>T p.S370= | Silent (SNP) | VAF 39/129 reads (30%) | called by muse, mutect2, varscan2
- FAT4 | c.2886C>T p.Y962= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs1302137252; ClinVar: likely benign; called by muse, mutect2, varscan2
- FFAR3 | c.588G>A p.P196= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs754166709, COSV100588222; called by muse, mutect2, varscan2
- FGD1 | c.2133C>A p.T711= | Silent (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
166 further variants in this file (0 protein-altering or splice-affecting, 147 silent, 19 other) are not listed here.
